Somatic mutation profile of tumor specimen TCGA-D3-A1Q4-06A (aliquot TCGA-D3-A1Q4-06A-11D-A196-08) from TCGA case TCGA-D3-A1Q4, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.0 years (19,716 days).
Specimen TCGA-D3-A1Q4-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd0f9440-bce2-483f-ab94-a0171ba75bdf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A1Q4-10A (Blood Derived Normal), aliquot TCGA-D3-A1Q4-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf8faa17-04ce-4d1d-92cf-29d4a599099e

The open-access MAF lists 321 somatic variants for this specimen: 201 protein-altering or splice-affecting, 108 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 185, Silent 108, Nonsense Mutation 9, 3'UTR 3, Frame Shift Del 3, Intron 3, RNA 3, Splice Site 2, 5'Flank 2, Frame Shift Ins 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 38/121 reads (31%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 18/55 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM981671, CM993670, COSV64293729, COSV64297280; called by muse, mutect2, varscan2
- ABCB4 | c.2443A>T p.T815S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV55939775, COSV99711066; called by muse, mutect2, varscan2
- ACE | c.401T>C p.L134P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV52024799; called by muse, mutect2
- ACE | c.3158T>C p.M1053T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52011354; called by muse, mutect2, varscan2
- ADAM29 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.194); catalogued as rs267600088, COSV63665430; called by muse, mutect2, varscan2
- AKAP6 | c.4313G>A p.G1438E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.017); catalogued as COSV55217455; called by muse, mutect2
- AL121899.2 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67351871; called by muse, mutect2, varscan2
- AMER1 | c.2833C>T p.P945S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as COSV57665055; called by muse, mutect2, varscan2
- AMHR2 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV57686579; called by muse, mutect2, varscan2
- ANKS1A | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs144301550, COSV64463138; called by muse, mutect2, varscan2
- ANO4 | c.2719C>T p.P907S (on ENST00000392977 / NM_001286615.2; = p.P872S on NM_178826.4) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54607153, COSV54607199; called by muse, mutect2, varscan2
- AOAH | c.398G>A p.W133* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as COSV51736137; called by muse, mutect2
- ASS1 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as rs1015400282, COSV61690292; called by muse, mutect2, varscan2
- ASTN2 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as rs779407243, COSV100529342; called by muse, varscan2
- B3GNTL1 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57952256; called by muse, mutect2, varscan2
- BCL9 | c.1489C>T p.L497F | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV52348456; called by muse, mutect2, varscan2
- BIRC3 | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54818900; called by muse, mutect2, varscan2
- BMPER | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.241); catalogued as COSV51827466; called by muse, mutect2, varscan2
- BRINP1 | c.2111A>T p.N704I | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs867136900, COSV56309115; called by muse, mutect2, varscan2
- CA4 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.053); catalogued as COSV56282273; called by muse, mutect2, varscan2
- CACNA1E | c.5956C>T p.P1986S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV62393695; called by muse, mutect2, varscan2
- CADM3 | c.430G>A p.E144K (on ENST00000368125 / NM_001127173.3; = p.E178K on NM_021189.5) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63684053; called by muse, mutect2, varscan2
- CAMKV | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV56557075; called by muse, mutect2, varscan2
- CCDC38 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1038390423, COSV60184291, COSV60184481; called by muse, mutect2, varscan2
- CCDC63 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV57527182; called by muse, mutect2
- CEP126 | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.149); catalogued as COSV54829008; called by muse, mutect2, varscan2
- CIT | c.5567C>T p.S1856F | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV55878329; called by muse, mutect2, varscan2
- CMYA5 | c.6133G>A p.E2045K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.651); catalogued as rs761485365, COSV71408420; called by muse, mutect2, varscan2
- CNGA2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.334); catalogued as COSV61703920; called by muse, mutect2, varscan2
- COL17A1 | c.2714C>A p.S905Y | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV62226094, COSV62228628; called by muse, mutect2, varscan2
- COL4A3 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1312532, COSV67418388; called by muse, mutect2, varscan2
- CPAMD8 | c.1837G>A p.E613K (on ENST00000651564; = p.E566K on NM_015692.5) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.69); catalogued as COSV52234099; called by muse, mutect2, varscan2
- CPN2 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV60471282; called by muse, mutect2, varscan2
- CPSF6 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.981); catalogued as COSV57017291; called by muse, mutect2, varscan2
- CYP17A1 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100882127; called by muse, mutect2, varscan2
- CYP3A43 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs189593899; called by muse, mutect2, varscan2
- DENND4A | c.4234G>A p.E1412K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0.054); catalogued as COSV71266734; called by muse, mutect2, varscan2
- DISC1 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV54400564, COSV99698347; called by muse, mutect2, varscan2
- DNAH5 | c.10054G>A p.E3352K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV54207833; called by muse, mutect2, varscan2
- DNAH8 | c.5123C>T p.S1708L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV100545329, COSV59469889; called by muse, mutect2, varscan2
- DNAH9 | c.2504C>T p.S835F | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV52339496, COSV52360552; called by muse, mutect2, varscan2
- DOCK4 | c.4249C>T p.R1417C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs377525977, COSV70240827; called by muse, mutect2, varscan2
- DOP1A | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52715166, COSV52717850; called by muse, mutect2, varscan2
- DRAM1 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV51599573; called by muse, mutect2, varscan2
- DSG1 | c.216+1G>A p.X72_splice | Splice Site (SNP) | VAF 11/64 reads (17%) | catalogued as rs866739374, COSV57138190; called by muse, mutect2, varscan2
- EFCAB3 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59503817; called by muse, mutect2
- EPPK1 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1554661529, COSV73261551; called by muse, mutect2, varscan2
- FAM71B | c.1016A>G p.E339G | Missense Mutation (SNP) | VAF 110/476 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV57230230; called by muse, mutect2
- FBXO40 | c.1863G>A p.W621* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as rs528828647, COSV100572871, COSV57526382; called by muse, mutect2, varscan2
- FBXW5 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1206809279, COSV56402751; called by mutect2, varscan2
- FGG | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60196319; called by muse, mutect2, varscan2
- FSD1 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV55698270; called by muse, mutect2, varscan2
- GABRE | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64818853; called by muse, mutect2, varscan2
- GAD1 | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64027070; called by muse, mutect2, varscan2
- GCOM1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.391); catalogued as COSV51094507; called by muse, mutect2, varscan2
- GJA8 | c.786A>C p.K262N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV53790032; called by muse, mutect2, varscan2
- GPM6A | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV54555129; called by muse, mutect2, varscan2
- GPR20 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as rs1195905004, COSV66684834; called by muse, mutect2, varscan2
- GRXCR2 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs754874283, COSV65061628; called by muse, mutect2, varscan2
- H3C3 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as COSV63551344; called by muse, mutect2, varscan2
- HAO1 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV66491625; called by muse, mutect2, varscan2
- HAVCR1 | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 76/347 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59402169; called by muse, mutect2, varscan2
- HP | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765891190, COSV63326307; called by muse, mutect2, varscan2
- HPR | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57184007; called by muse, mutect2, varscan2
- HSPA5 | c.1371T>A p.N457K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV52337478, COSV52338283; called by muse, mutect2, varscan2
- HTR2C | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52200883, COSV52216790; called by muse, mutect2, varscan2
- HTR3A | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs746743815, COSV55470741, COSV55471627; called by muse, mutect2, varscan2
- IGSF21 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.267); catalogued as rs267598244, COSV52124620; called by muse, mutect2, varscan2
- IL7R | c.879T>A p.N293K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100285940, COSV57411536; called by muse, mutect2
- ISL1 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs764011682, COSV57935053; called by muse, mutect2, varscan2
- ITGA5 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.675); catalogued as COSV53219825; called by muse, mutect2, varscan2
- ITPRID2 | c.2410C>T p.P804S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs540962657, COSV57474159, COSV57475085; called by muse, mutect2, varscan2
- KCNC4 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63926319; called by muse, mutect2, varscan2
- KCNK2 | c.398G>A p.G133E (on ENST00000444842 / NM_001017425.3; = p.G118E on NM_014217.4) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV67207137; called by muse, mutect2, varscan2
- KIR3DL1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58494612; called by muse, mutect2, varscan2
- KLK2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.479); catalogued as COSV57568643; called by muse, mutect2, varscan2
- KRT1 | c.636G>A p.W212* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV52868440; called by muse, mutect2, varscan2
- KRT8 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV53178632; called by muse, varscan2
- KRTAP10-1 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs1555916918, COSV59973643; called by muse, mutect2, varscan2
- LAMA4 | c.5075A>G p.N1692S (on ENST00000230538 / NM_001105206.3; = p.N1685S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as rs1414574619, COSV57902646; called by muse, mutect2, varscan2
- LARP1B | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs755964100, COSV52801269; called by muse, mutect2, varscan2
- LARP4B | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV60222938; called by muse, mutect2, varscan2
- LIPN | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68384346; called by muse, mutect2, varscan2
- LMTK2 | c.2608C>T p.L870F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV51990838, COSV52001306; called by muse, mutect2, varscan2
- LPO | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV51861337; called by muse, mutect2, varscan2
- LRP1B | c.2863C>A p.Q955K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV67256974, COSV67257928; called by muse, mutect2
- LRRC18 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263162099, COSV53285150; called by muse, mutect2, varscan2
- MAGEB18 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57464759; called by mutect2, varscan2
- MAP3K3 | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.531); catalogued as rs1227087534, COSV62281348; called by muse, mutect2
- MBL2 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs1209288010, COSV64759143; called by muse, mutect2
- MDGA1 | c.123C>A p.D41E | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV51800015; called by muse, mutect2, varscan2
- MECOM | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72110994; called by muse, mutect2, varscan2
- MMP7 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.593); catalogued as rs1244583716, COSV52772892; called by muse, mutect2, varscan2
- MOK | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.557); catalogued as COSV51966826; called by muse, mutect2, varscan2
- MROH7 | c.2894A>G p.Y965C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59875859; called by muse, mutect2, varscan2
- MTUS1 | c.2288-1G>A p.X763_splice | Splice Site (SNP) | VAF 21/79 reads (27%) | catalogued as COSV50575051; called by muse, mutect2, varscan2
- MUC16 | c.19438G>A p.G6480R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.087); catalogued as COSV101200666; called by muse, mutect2, varscan2
- MUC16 | c.17692C>T p.P5898S | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV67468056; called by muse, mutect2, varscan2
- MYH4 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV55123546; called by muse, mutect2, varscan2
- MYH8 | c.4495G>A p.E1499K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs370499944; called by muse, mutect2, varscan2
- MYO18B | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs780287472, COSV59124242; called by mutect2, varscan2
- MYOCD | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs867825202, COSV58509032; called by muse, mutect2, varscan2
- MYOCD | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58509052; called by muse, mutect2, varscan2
- NAV3 | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV57101990; called by muse, mutect2, varscan2
- NDST4 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs776446264, COSV52131046; called by muse, mutect2, varscan2
- NEXMIF | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50027881; called by muse, mutect2, varscan2
- NIPAL4 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.123); catalogued as COSV57436130; called by muse, mutect2, varscan2
- NLRP13 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV61623498; called by muse, mutect2, varscan2
- NOTCH4 | c.5531G>C p.R1844P | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV66678513; called by muse, mutect2, varscan2
- NR2F1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.325); catalogued as COSV59067534; called by muse, mutect2, varscan2
- NTN4 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs193920922, COSV59222574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NYNRIN | c.3659C>T p.S1220F | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV66841974; called by muse, mutect2, varscan2
- OR10G2 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as rs541165979, COSV73390434; called by muse, mutect2, varscan2
- OR13C4 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1442265423, COSV52927930; called by muse, mutect2, varscan2
- OR2F2 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV68832948; called by muse, mutect2, varscan2
- OR51Q1 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56179471; called by muse, mutect2, varscan2
- PAPPA2 | c.1999A>G p.M667V | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV62783443; called by muse, mutect2, varscan2
- PAX9 | c.804T>A p.F268L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV100492066; called by muse, mutect2, varscan2
- PAX9 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV100492067; called by muse, mutect2, varscan2
- PCDHA1 | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65376118; called by muse, mutect2, varscan2
- PCDHB9 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as COSV53382134; called by muse, mutect2, varscan2
- PCDHGA3 | c.1595T>G p.V532G | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV54002920; called by muse, mutect2, varscan2
- PCF11 | c.3178G>T p.G1060C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV53535941; called by muse, mutect2, varscan2
- PCSK4 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200902458, COSV52014631; called by muse, mutect2, varscan2
- PDK3 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as rs1192081613, COSV64793994, COSV64794050; called by muse, mutect2, varscan2
- PLCG1 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV54821895; called by muse, mutect2, varscan2
- PLEKHG3 | c.1961C>T p.S654F (on ENST00000394691; = p.S710F on NM_001308147.2) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55977922; called by muse, mutect2, varscan2
- POP1 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs149744031; called by muse, mutect2, varscan2
- PPARG | c.946C>T p.R316C (on ENST00000287820 / NM_015869.5; = p.R286C on NM_005037.7) | Missense Mutation (SNP) | VAF 118/407 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1364613522, COSV55144557; called by muse, mutect2, varscan2
- PPFIA2 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV61046764; called by muse, mutect2, varscan2
- PPP6R2 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.72); catalogued as rs566684286, COSV99324607; called by muse, varscan2
- PREX2 | c.4493G>C p.C1498S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.041); catalogued as COSV55791771; called by muse, mutect2
- PRX | c.3160G>A p.G1054R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV52532385, COSV99397551; called by muse, mutect2, varscan2
- PTPRH | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV54748419; called by muse, mutect2, varscan2
- PTPRH | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV54748205; called by muse, mutect2, varscan2
- PYDC2 | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as COSV72921351, COSV72921413; called by muse, mutect2, varscan2
- RAB11FIP5 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50254771; called by muse, varscan2
- RAD51AP2 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV67588760; called by muse, mutect2, varscan2
- RAD51C | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs28363311, CM120336; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RALGDS | c.422C>T p.T141I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64428977; called by muse, mutect2, varscan2
- RAMP3 | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as rs1444923499, COSV54245761; called by muse, mutect2, varscan2
- RAPGEF3 | c.2482G>A p.G828R (on ENST00000389212; = p.G786R on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50218977; called by muse, mutect2, varscan2
- RBFOX1 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV60973145; called by muse, mutect2, varscan2
- RBM25 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV99998773; called by muse, mutect2, varscan2
- RECK | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV65036033; called by muse, mutect2, varscan2
- REG1B | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.42); catalogued as COSV100521473; called by muse, varscan2
- RELN | c.1865C>T p.T622I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59024700; called by muse, mutect2, varscan2
- ROCK1 | c.1673C>A p.S558* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV67695330, COSV67698174; called by muse, mutect2, varscan2
- ROR2 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65217230; called by muse, mutect2, varscan2
- RPS6KA6 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV53124272; called by muse, mutect2, varscan2
- S100A10 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as rs372399834; called by muse, mutect2, varscan2
- SAGE1 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV61016085; called by muse, mutect2, varscan2
- SCN1A | c.5735G>A p.R1912Q (on ENST00000303395 / NM_001202435.3; = p.R1901Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs373896263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNN1B | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56308428; called by muse, mutect2, varscan2
- SEC14L5 | c.1877G>A p.C626Y | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0.096); catalogued as COSV52040671; called by mutect2, varscan2
- SGIP1 | c.1747A>T p.I583F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV52775798; called by muse, mutect2, varscan2
- SH3GL3 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs373378258; called by muse, mutect2, varscan2
- SLC22A16 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57932996; called by muse, mutect2, varscan2
- ST6GAL2 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | PolyPhen possibly damaging (0.704); catalogued as COSV64530618; called by muse, mutect2, varscan2
- STXBP5L | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56527178; called by muse, mutect2
- SUN2 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs770399092, COSV53304276; called by muse, varscan2
- SVEP1 | c.8289G>A p.W2763* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as COSV52842419; called by muse, mutect2, varscan2
- SYNGAP1 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53385101; called by muse, mutect2, varscan2
- TAF2 | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV65417976; called by muse, mutect2, varscan2
- TAOK3 | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.52); catalogued as COSV66827179; called by muse, mutect2, varscan2
- TAOK3 | c.2677C>T p.P893S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.027); catalogued as COSV101183675; called by muse, mutect2, varscan2
- TAS1R2 | c.1021T>G p.W341G | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as COSV64746462, COSV64746791; called by muse, mutect2, varscan2
- TCN2 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs1258577765, COSV53192497; called by muse, mutect2, varscan2
- THSD7B | c.3967G>A p.E1323K (on ENST00000272643; = p.E1321K on NM_001316349.2) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV55721181; called by muse, mutect2
- TLR2 | c.1814C>T p.T605M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1477664551; called by mutect2, varscan2
- TMEM74 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52464302; called by muse, varscan2
- TNR | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as rs531733667, COSV54868765; called by muse, mutect2, varscan2
- TNR | c.2528A>G p.N843S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV54904618; called by muse, mutect2, varscan2
- TRIOBP | c.1064G>A p.R355K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.138); catalogued as COSV60382191; called by muse, mutect2, varscan2
- TSHZ1 | c.878C>T p.S293F (on ENST00000580243 / NM_001308210.2; = p.S248F on NM_005786.6) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100433866; called by muse, mutect2, varscan2
- TTN | c.100389G>A p.M33463I (on ENST00000591111; = p.M26039I on NM_003319.4) | Missense Mutation (SNP) | VAF 31/122 reads (25%) | PolyPhen benign (0.005); catalogued as COSV60244169; called by muse, mutect2, varscan2
- TTN | c.20179C>T p.P6727S (on ENST00000591111; = p.P5800S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | PolyPhen benign (0.067); catalogued as rs773899102, COSV60244216; called by muse, mutect2, varscan2
- TTYH2 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1167637036, COSV53912578; called by muse, mutect2, varscan2
- UNC5D | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV54768742, COSV54821124; called by muse, mutect2, varscan2
- VIRMA | c.4332C>G p.S1444R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.063); catalogued as COSV52589223; called by muse, mutect2, varscan2
- VWA3B | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as rs1299336855, COSV68242088; called by muse, mutect2, varscan2
- VWC2 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV61489630; called by muse, mutect2, varscan2
- WDR59 | c.2000T>G p.I667R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV50941145; called by muse, mutect2, varscan2
- WWC1 | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 35/137 reads (26%) | catalogued as rs762385434, COSV54651182; called by muse, mutect2, varscan2
- ZBED4 | c.618C>G p.I206M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs1364288914, COSV53467288; called by muse, mutect2, varscan2
- ZBTB7A | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59328458; called by muse, mutect2, varscan2
- ZC4H2 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62003450; called by muse, mutect2, varscan2
- ZNF208 | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV68110714; called by muse, mutect2
- ZNF232 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV51504568; called by muse, mutect2, varscan2
- ZNF251 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.268); catalogued as COSV52958584; called by muse, mutect2, varscan2
- ZNF418 | c.1714G>C p.G572R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV68676237; called by muse, mutect2, varscan2
- ZNF676 | c.1705G>A p.E569K (on ENST00000650058; = p.E537K on NM_001001411.3) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68092337, COSV68094305; called by muse, mutect2
- ABCA1 | c.948dup p.L317Afs*10 | Frame Shift Ins (INS) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- CASC3 | c.1670del p.I557Tfs*22 | Frame Shift Del (DEL) | VAF 22/144 reads (15%) | called by mutect2, pindel*, varscan2
- CLEC16A | c.2885_2886del p.S962* | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | called by pindel, varscan2
- IGHV3-43 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/74 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- PRAMEF18 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- RAB11FIP5 | c.783_786del p.S262Gfs*144 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by pindel, varscan2
- RBP3 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ABCA12 | c.3795C>T p.F1265= (on ENST00000272895 / NM_173076.3; = p.F947= on NM_015657.3) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV55969992, COSV55970062; called by muse, mutect2, varscan2
- AC092143.1 | c.2007C>T p.S669= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs866808095, COSV59247533; called by muse, mutect2, varscan2
- APLP1 | c.1152C>T p.I384= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV55705308; called by muse, mutect2, varscan2
- ARSH | c.696C>T p.I232= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV66963903; called by muse, mutect2, varscan2
- BDP1 | c.1188C>T p.S396= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs902906277, COSV62433347; called by muse, mutect2, varscan2
- BSPRY | c.702C>T p.I234= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs369636312; called by muse, mutect2, varscan2
- BTBD16 | c.207T>C p.N69= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1317817471, COSV53265890; called by muse, mutect2, varscan2
- C2orf16 | c.2175G>A p.G725= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs773407710, COSV62677444; called by muse, mutect2, varscan2
- CCDC144A | c.3621G>A p.R1207= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV60700598; called by muse, mutect2, varscan2
- CEMIP | c.1917C>T p.L639= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV54997877; called by muse, mutect2, varscan2
- CLIC5 | c.1188C>T p.I396= (on ENST00000185206 / NM_001370649.1; = p.I237= on NM_016929.5) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs755770652, COSV51755675; called by muse, mutect2, varscan2
- COL13A1 | c.930C>T p.I310= (on ENST00000398978 / NM_001130103.2; = p.I253= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1007858876, COSV62573095; called by muse, mutect2, varscan2
- CPLX3 | c.126G>A p.E42= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100547785; called by muse, mutect2, varscan2
- CXCR4 | c.120C>T p.F40= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV54015267; called by muse, mutect2, varscan2
- CYP4F12 | c.907C>T p.L303= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV61175594; called by muse, mutect2, varscan2
- DISC1 | c.594C>T p.T198= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99698351; called by muse, mutect2, varscan2
- DISP1 | c.111C>A p.A37= | Silent (SNP) | VAF 20/491 reads (4%) | catalogued as COSV52656784, COSV52663056; called by muse, mutect2
- DLG4 | c.1704G>A p.R568= (on ENST00000399506 / NM_001321075.3; = p.R611= on NM_001365.4) | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as COSV57241043; called by muse, mutect2, varscan2
- DNAH5 | c.8364C>T p.F2788= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV54241051; called by muse, mutect2, varscan2
- DPH7 | c.927C>T p.I309= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs531775600, COSV53023342; called by muse, mutect2, varscan2
- DSC1 | c.837G>A p.L279= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs1236708914, COSV57149494; called by muse, mutect2, varscan2
- DSCAM | c.252C>T p.F84= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs747859049, COSV68631659; called by muse, mutect2, varscan2
- ENTPD1 | c.495T>C p.G165= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV64603594; called by muse, mutect2, varscan2
- EPB41L4B | c.1626C>T p.S542= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as rs1228493959, COSV65804521; called by muse, mutect2, varscan2
- ERBB4 | c.1242C>T p.F414= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV53531139, COSV53566388; called by muse, mutect2, varscan2
- FAM71B | c.1014A>T p.S338= | Silent (SNP) | VAF 114/478 reads (24%) | catalogued as COSV57230236; called by muse, mutect2
- FAM83A | c.702G>A p.R234= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs267601760, COSV52686989; called by muse, mutect2, varscan2
- FAT3 | c.2706G>A p.L902= | Silent (SNP) | VAF 122/469 reads (26%) | catalogued as COSV53154553; called by muse, mutect2, varscan2
- FBXO24 | c.354A>T p.G118= (on ENST00000241071 / NM_033506.3; = p.G156= on NM_012172.5) | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as rs1453433041, COSV53828476; called by muse, mutect2, varscan2
- FCAR | c.687C>T p.I229= | Silent (SNP) | VAF 71/425 reads (17%) | catalogued as COSV62031216; called by muse, mutect2, varscan2
- FGF9 | c.552C>T p.F184= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV66644126; called by muse, mutect2, varscan2
- FKBP8 | c.810G>A p.L270= (on ENST00000222308 / NM_001308373.2; = p.L271= on NM_012181.5) | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1337572806, COSV55893461; called by muse, mutect2, varscan2
- FZD1 | c.1488C>T p.F496= | Silent (SNP) | VAF 51/186 reads (27%) | catalogued as rs267601624, COSV55310544; called by muse, mutect2, varscan2
- GEM | c.378G>A p.T126= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs763307759, COSV52598628; called by muse, mutect2, varscan2
- GPNMB | c.306C>T p.F102= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as COSV51700135; called by muse, mutect2, varscan2
- GRAMD1C | c.1782C>T p.L594= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV63983805; called by muse, mutect2, varscan2
- GTF3C2 | c.1884C>T p.F628= | Silent (SNP) | VAF 87/325 reads (27%) | catalogued as rs749203416, COSV53128191, COSV53128786; called by muse, mutect2, varscan2
- HBE1 | c.27G>A p.K9= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs1017273128, COSV53080831; called by muse, mutect2, varscan2
- HECW1 | c.4644C>T p.L1548= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs1213772338, COSV67836870; called by muse, mutect2, varscan2
- IGFN1 | c.3303C>T p.L1101= (on ENST00000295591 / NM_001367841.1; = p.L3558= on NM_001164586.2) | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs777985293, COSV55180360; called by muse, mutect2, varscan2
- IGKV1D-17 | c.51C>T p.F17= | Silent (SNP) | VAF 20/105 reads (19%) | called by muse, mutect2, varscan2
- IQGAP3 | c.4128C>T p.I1376= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV63253659, COSV63255076; called by muse, mutect2, varscan2
- ITGB8 | c.870C>T p.L290= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs763523589, COSV56011429; called by muse, mutect2, varscan2
- KCNJ1 | c.867G>A p.Q289= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1444358581, COSV60662460; called by muse, mutect2, varscan2
- KCNK13 | c.1188C>T p.I396= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99965622; called by muse, mutect2, varscan2
- KCNQ5 | c.2415G>A p.R805= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV59653299; called by muse, mutect2, varscan2
- KRTAP5-9 | c.342C>T p.P114= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV73200247; called by muse, mutect2, varscan2
- MACF1 | c.81G>A p.R27= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV58392908; called by mutect2, varscan2
- MARCHF6 | c.2004G>A p.G668= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV56885014; called by muse, mutect2, varscan2
- MMP17 | c.1197C>T p.F399= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV62180762; called by muse, mutect2, varscan2
- MRGPRD | c.15G>A p.L5= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100483047, COSV58423847; called by muse, mutect2, varscan2
- MRTFA | c.909C>T p.S303= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs771855607, COSV62935473; called by muse, mutect2, varscan2
- MUC16 | c.26298C>T p.S8766= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV101200054, COSV67482431; called by muse, mutect2, varscan2
- MYH2 | c.1581C>T p.I527= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs1050588952, COSV55432408, COSV55447489; called by muse, mutect2, varscan2
- MYOM2 | c.2544C>T p.F848= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs558634230, COSV50732142; called by muse, mutect2, varscan2
- NKAIN2 | c.138C>T p.I46= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs746180378, COSV63679539; called by muse, mutect2, varscan2
- NRP2 | c.1434C>T p.I478= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs566838427, COSV55932905; called by muse, mutect2, varscan2
- NUP188 | c.1161C>T p.F387= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs754618744, COSV65360578; called by muse, mutect2, varscan2
- OGDH | c.2655C>T p.I885= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV56054794; called by muse, mutect2, varscan2
- OR10H3 | c.186C>T p.L62= | Silent (SNP) | VAF 47/256 reads (18%) | catalogued as COSV59944527; called by muse, mutect2, varscan2
- OR10W1 | c.909G>A p.Q303= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV67720745; called by mutect2, varscan2
- OR1D2 | c.94C>T p.L32= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV58922173; called by muse, mutect2, varscan2
- OR1N1 | c.117G>A p.G39= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV59197169; called by muse, mutect2, varscan2
- OR2A2 | c.823C>T p.L275= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as rs753114056, COSV101286686, COSV68872232; called by muse, mutect2, varscan2
- OR4C13 | c.654C>T p.V218= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV73648862; called by muse, mutect2, varscan2
- OR4D5 | c.934C>T p.L312= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV58306371, COSV58308699; called by muse, varscan2
- OR4N2 | c.795C>T p.F265= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs865793079, COSV100269698, COSV60051246; called by muse, mutect2, varscan2
- OR52E6 | c.153C>T p.I51= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100259300, COSV61432903; called by muse, mutect2, varscan2
- OR6C70 | c.465C>T p.F155= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV59245214, COSV59245231; called by muse, mutect2, varscan2
- OR6C74 | c.84C>T p.L28= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs755606993, COSV59607024; called by muse, mutect2, varscan2
- OR6F1 | c.771C>T p.F257= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs777051434, COSV57466858; called by muse, mutect2, varscan2
- OR8B8 | c.123G>A p.G41= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs866729866, COSV60145360; called by muse, mutect2, varscan2
- PCDHA13 | c.270C>T p.I90= | Silent (SNP) | VAF 41/221 reads (19%) | catalogued as rs782086663, COSV56477733; called by muse, mutect2, varscan2
- PCDHA9 | c.204C>T p.S68= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as COSV65330845; called by muse, mutect2, varscan2
- PCDHGB4 | c.411C>T p.S137= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs766909730, COSV53911131; called by muse, mutect2, varscan2
- PGK2 | c.321C>T p.A107= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs1029425046, COSV59164932; called by muse, mutect2, varscan2
- PLEKHA7 | c.1471C>T p.L491= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as COSV63049430; called by muse, mutect2, varscan2
- PLXNB2 | c.2514C>T p.I838= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV63783602; called by muse, mutect2, varscan2
- PPM1G | c.126T>C p.A42= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV59771009; called by muse, mutect2
- PPP6R2 | c.1209C>T p.A403= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV53299606; called by muse, mutect2, varscan2
- PRAMEF15 | c.396G>A p.R132= | Silent (SNP) | VAF 28/414 reads (7%) | called by muse, mutect2
- PREX2 | c.2532T>A p.G844= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- PRRT3 | c.144G>A p.K48= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs747358409, COSV55976870; called by muse, mutect2, varscan2
- QRICH2 | c.4689C>A p.T1563= | Silent (SNP) | VAF 29/152 reads (19%) | catalogued as COSV53156478; called by muse, mutect2, varscan2
- RABL2B | c.378C>T p.I126= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV61483788; called by mutect2, varscan2
- RGS5 | c.423G>A p.K141= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV58353692; called by muse, mutect2, varscan2
- SAMD9 | c.1437G>A p.T479= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs748738937, COSV66073133; called by muse, mutect2, varscan2
- SCN3A | c.2433C>T p.I811= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs1324198307, COSV51814848; called by muse, mutect2, varscan2
- SLC22A25 | c.111G>A p.L37= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs771774500, COSV60598056; called by muse, varscan2
- SPATA31E1 | c.435G>A p.R145= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs557271460, COSV100350825; called by muse, mutect2, varscan2
- STXBP5L | c.2598C>T p.S866= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV56527188; called by muse, mutect2, varscan2
- SYMPK | c.231C>T p.I77= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV55614511; called by muse, mutect2, varscan2
- TAFA2 | c.363G>A p.G121= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV69184819; called by muse, mutect2, varscan2
- TBCE | c.87C>T p.V29= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV64007044; called by muse, mutect2, varscan2
- TBL2 | c.975C>T p.R325= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as COSV59787876; called by muse, mutect2, varscan2
- TENM4 | c.5178C>T p.V1726= | Silent (SNP) | VAF 40/157 reads (25%) | catalogued as COSV53655572; called by muse, mutect2, varscan2
- TGM6 | c.882C>T p.V294= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs762965769, COSV52482870; called by muse, mutect2, varscan2
- TMEM92 | c.336C>T p.S112= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs267604949, COSV55946669; called by mutect2, varscan2
- TRIM62 | c.753G>C p.L251= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV52222933; called by muse, mutect2, varscan2
- TRPC6 | c.1665G>A p.Q555= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100723778, COSV60258921; called by muse, mutect2
- TSHZ1 | c.879C>T p.S293= (on ENST00000580243 / NM_001308210.2; = p.S248= on NM_005786.6) | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs904159313, COSV100433867; called by muse, mutect2, varscan2
- TTN | c.54237G>A p.Q18079= (on ENST00000591111; = p.Q10655= on NM_003319.4) | Silent (SNP) | VAF 56/230 reads (24%) | catalogued as COSV60244193; called by muse, mutect2, varscan2
- TTN | c.22992G>A p.R7664= (on ENST00000591111; = p.R6737= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs1294697191, COSV60070200; called by muse, mutect2, varscan2
- VIL1 | c.2250G>A p.V750= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs752442648, COSV50293454; called by muse, mutect2, varscan2
- ZBED9 | c.1164G>A p.G388= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV71729675; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1548C>T p.G516= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs965569451, COSV52851985; called by muse, mutect2, varscan2
- ZNF280A | c.69G>A p.R23= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV57481756; called by muse, mutect2, varscan2
- ZNF529 | c.1492A>C p.R498= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV61901508; called by muse, mutect2, varscan2
- AL133467.5 | chr14:95663544 C>T | 3'Flank (SNP) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- AL353804.4 | chrX:73824668 C>T | 5'Flank (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- AL645922.1 | c.256+715G>A | Intron (SNP) | VAF 77/318 reads (24%) | catalogued as COSV54961941; called by muse, mutect2, varscan2
- CLLU1 | chr12:92421037 C>T | 5'Flank (SNP) | VAF 55/253 reads (22%) | catalogued as COSV65903090; called by muse, mutect2, varscan2
- CPLANE1 | c.*3983C>T | 3'UTR (SNP) | VAF 6/30 reads (20%) | catalogued as COSV57069535; called by muse, mutect2
- HNF4A | c.115+1154G>A | Intron (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- MIR1283-2 | n.62C>T | RNA (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- MIR518A1 | n.79T>G | RNA (SNP) | VAF 13/69 reads (19%) | called by muse, varscan2
- MIR522 | n.15C>T | RNA (SNP) | VAF 41/103 reads (40%) | called by muse, mutect2, varscan2
- PRELP | c.*1G>A | 3'UTR (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100557912; called by muse, mutect2, varscan2
- RRP7A | c.*3802G>C | 3'UTR (SNP) | VAF 9/64 reads (14%) | catalogued as rs759314345; called by muse, mutect2, varscan2
- TTN | c.34265-4841C>T | Intron (SNP) | VAF 70/260 reads (27%) | catalogued as COSV100623391; called by muse, mutect2, varscan2
